Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A6E4, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A6E4-01A (Primary Tumor).

[page 1 of 3]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) RIGHT PELVIC LYMPH NODES:
Two lymph nodes, no tumor present.
- (B) LEFT PELVIC LYMPH NODES:
Two lymph nodes, no tumor present.
- (C) PROSTATE AND SEMINAL VESICLES:
Supplemental report to follow.

Entire report and diagnosis completed by

path ICD-O-3
Adenocarcinoma NOS
8140/3
conf
Adenocarcinoma, acinar
8140/3
Site Prostate NOS
C61.9
4/25/13

GROSS DESCRIPTION

- (A) RIGHT PELVIC LYMPH NODES - Two lymph nodes measuring 8.0 x 3.0 x 1.0 and 1.0 x 0.5 x 0.5 cm.
SECTION CODE: A1, one lymph node; A2-A15, serial sections of one lymph node.
*FS/DX: TWO LYMPH NODES, NO TUMOR PRESENT.
- (B) LEFT PELVIC LYMPH NODES - Two lymph nodes (4.5 x 1.8 x 1.0 and 5.4 x 1.2 x 1.2 cm).
SECTION CODE: B1-B4, one lymph node serially sectioned; B5-B8, one lymph node serially sectioned.
- (C) PROSTATE AND SEMINAL VESICLES - Supplemental report to follow.

CLINICAL HISTORY

History of prostate cancer.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Released by:

Start of ADDENDUM

[page 2 of 3]
Specimen Date/Time:

ADDENDUM

Addendum completed by

DIAGNOSIS

(C) PROSTATE AND SEMINAL VESICLES:

PROSTATIC ADENOCARCINOMA, GLEASON SCORE 7 (3+4). (SEE COMMENT)

TUMOR CONFINED TO THE PROSTATE.

Margins of resection free of tumor.

PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN), HIGH-GRADE.

Right and left seminal vesicles, no tumor present.

Segments of right and left vasa deferentia, no tumor present.

COMMENT

The prostate gland contains a single focus of prostatic adenocarcinoma. The tumor involves the right anterolateral, right lateral and right posterolateral peripheral zone with extension into the right transition zone. The tumor focus measures 2.5 x 1.5 cm in the largest cross-sectional dimension, and it is present in the three cross-sections of the prostate, extensively in the apex, and focally in the base region. The tumor is confined to the prostate. The margins of resection are free of tumor.

GROSS DESCRIPTION

(C) PROSTATE AND SEMINAL VESICLES - A specimen consisting of a prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (4.5 x 2.9 x 4.6 cm, 37.5 grams, post-fixation) has the usual shape. The soft tissue present along the right posterolateral aspect of the prostate appears more abundant than along the left side. A nodule is palpated in the right posterolateral aspect of the prostate. Serial cross-sections after fixation demonstrate an area consistent with tumor in the right peripheral zone extending from the first to the third cross-sections.

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

SECTION CODE: C1, C2, base of right seminal vesicle and right vas deferens; C3, C4, base of left seminal vesicle and left vas deferens; C5, prostatic base right border; C6, C7, prostatic base right posterior border; C8-C12, prostatic base central portion; C13, prostatic base left border; C14, C15, prostatic base left posterior border; C16, C17, apex anterior; C18, C19, apex left; C20-C23, apex posterior; C24, C25, apex right; C26, detached portions of margin of resection according to specimen radiograph; C27-C38, sections of the three cross-sections of the prostate according to specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black. Blue ink (C19-22, 28) and orange ink (C33, 34 and 38) denote surfaces which do not represent a true margin of resection.

SNOMED CODES

Released by:

[page 3 of 3]
Specimen Date/Time:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 8110e479-bca5-4821-bf4f-d3b06b10bfce (TCGA-KK-A6E4.D4A30E0D-4829-4B4E-863A-DF2ACED85BE8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).